Gene-level copy-number profile of tumor specimen TCGA-4B-A93V-01A from TCGA case TCGA-4B-A93V, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 52.1 years (19,035 days).
Specimen TCGA-4B-A93V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.fe4322e4-f010-43a6-868a-5b9fe58f076d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-4B-A93V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e27f6d50-c9f3-40df-8d65-42714bc224b5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,692; copy number 2: 35,634; copy number 3: 8,110; copy number 4: 12,523; copy number 5: 707; copy number 6: 81; copy number 7: 21; copy number 8: 666; copy number 10: 111; copy number 11: 23; copy number 12: 72; copy number 13: 6; copy number 14: 60; copy number 18: 104; copy number 25: 3; copy number 28: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-4B-A93V-01A-11D-A396-01): tumor purity 0.62, ploidy 2.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,855 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:24,729,379–27,121,150, 29 genes, copy number 5 (within-gene range 3–5): AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P, AC025475.1, AC025475.2, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9.
- chr5:42,917,414–45,895,970, 50 genes, copy number 5: PRELID3BP6, PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr8:120,059,780–141,518,737, 284 genes, copy number 8–13 (within-gene range 3–13) (broad region; genes not listed).
- chr10:44,712–38,783,108, 675 genes, copy number 5–11 (broad region; genes not listed).
- chr11:84,887,207–89,301,477, 81 genes, copy number 6 (broad region; genes not listed).
- chr14:18,333,726–41,298,734, 705 genes, copy number 8–28 (broad region; genes not listed).
- chr18:56,003,613–57,964,434, 31 genes, copy number 5: AC006305.1, AC009271.2, LINC01905, AC006305.2, SNORA73, LINC01539, AC006305.3, TXNL1, WDR7, Y_RNA, AC012301.1, U3, WDR7-OT1, AC012301.2, LINC-ROR, AC100775.1, BOD1L2, LINC02565, RNU6-737P, ST8SIA3, AC090340.1, ONECUT2, FECH, AC100847.1, NARS1, AC027097.1, AC027097.2, ATP8B1, RNU6-742P, RSL24D1P11, LINC01897.

Autosomal genes at a single copy (total copy number 1): 1,692. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
